Surgical pathology report (de-identified scan), TCGA case TCGA-61-2095, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2095-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

PART 1: "TUMOR", EXCISION -

METASTATIC CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 2: "TUMOR", EXCISION -

METASTATIC CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 3: PORTION OF SMALL BOWEL, RESECTION -

A. METASTATIC CARCINOMA INVOLVING BOWEL WALL.

B. PROXIMAL AND DISTAL RESECTION MARGINS ARE NEGATIVE FOR TUMOR.

COMMENT:

The tumor morphology is consistent with patient's known ovarian serous carcinoma [REDACTED]

ICD-0-3 Recurrence
carcinoma, NOS, metastatic 8010/6
Site: bowel, NOS C26.0

hw
2/12/15

Source: NCI Genomic Data Commons file 0476ed6a-0a2b-4d15-8474-5b8363be56d2 (TCGA-61-2095.309AA9DC-F958-45C3-B596-362ADA553B8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).